Gene-level copy-number profile of tumor specimen ALCH-B2M0-TTP1-A from ALCHEMIST case ALCH-B2M0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenosquamous carcinoma; Age at diagnosis: 80.3 years (29,314 days).
Specimen ALCH-B2M0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ed595da5-b471-46fc-8107-653df0e790dc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2M0-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,727 have no estimate.
https://portal.gdc.cancer.gov/files/b509839d-1d04-4e33-82d4-10fa30a472ed

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 3,076; copy number 2: 55,293; copy number 3: 472; copy number 4: 22; copy number 5: 9; copy number 10: 4; copy number 11: 3.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 16 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:120,354,987–120,355,148, 1 gene, copy number 5: U1.
- chr15:30,135,149–30,254,508, 8 genes, copy number 5–10: GOLGA8T, RN7SL469P, DNM1P30, AC120045.2, AC120045.1, LINC02249, AC135731.1, RNU6-17P.
- chr15:30,470,779–30,614,561, 7 genes, copy number 5–11 (within-gene range 2–11): AC127502.1, AC127502.2, AC127502.3, AC026150.2, AC026150.1, GOLGA8H, AC026150.3.

Autosomal genes at a single copy (total copy number 1): 249. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
